TCGA case TCGA-DX-A6YV — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Fibromatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6be3885c-219b-44f4-92bc-c055dc843a87

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 74 years; Vital status: Dead; Days to death: 1,536 days (4.2 years).

Diagnoses (2)
1. Fibromyxosarcoma (the primary disease): ICD-O-3 morphology code: 8811/3; ICD-10 code: C49.2; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of lower limb and hip; Classification of tumor: primary; Age at diagnosis: 74.1 years (27,053 days); Year of diagnosis: 2008; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Lymph Node, Inguinal; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 11; Tumor length measurement: 19; Tumor width measurement: 14.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis percent: 35; Necrosis present: Yes; Tumor depth descriptor: Deep.
2. Metastasis of diagnosis 1 (Fibromyxosarcoma), site: Lymph nodes of inguinal region or leg. Age at diagnosis: 75.5 years (27,569 days); Days to diagnosis: 516 days (1.4 years); Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 2.5; Tumor length measurement: 3.9; Tumor width measurement: 2.5.

Follow-up (2 entries)
- Day 516 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lymph nodes of inguinal region or leg; Days to progression: 516 days (1.4 years).
- Days to follow up: 1,536 days (4.2 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-A6YV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 260 mg.
  Slide TCGA-DX-A6YV-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DX-A6YV-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DX-A6YV-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Myxofibrosarcoma; Margin status: Negative; Tumor total necrosis: Moderate Necrosis (>=10, <50%); Disease multifocal indicator: No; Locoregional recurrence indicator: No; Metastatic disease confirmed: Yes; Metastasis site: Groin - lymph nodes.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower Extremity - Thigh/knee.
- Radiation treatment 1: Days from index date to radiation therapy started: 585; Days from index date to radiation therapy ended: 627; Radiation therapy type: External; Radiation total dose: 6000; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 30; Radiation therapy site: Distant Recurrence; Radiation therapy ongoing indicator: No; Treatment best response: Radiographic Progressive Disease.
- Radiation treatment 2: Days from index date to radiation therapy started: 795; Days from index date to radiation therapy ended: 823; Radiation therapy type: External; Radiation total dose: 3500; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 14; Radiation therapy site: Distant Recurrence; Radiation therapy ongoing indicator: No; Treatment best response: Radiographic Progressive Disease.
- Radiation treatment 3: Days from index date to radiation therapy started: 1369; Days from index date to radiation therapy ended: 1387; Radiation therapy type: External; Radiation therapy site: Distant Recurrence; Radiation therapy ongoing indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,536 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,536 days; disease-free interval: event (new tumor event after initially disease-free), 516 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 516 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-A6YV-01A-12D-A350-01): tumor purity 0.94, ploidy 2.79, whole-genome doublings 1.
